TCGA case TCGA-L4-A4E6 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Gundersen Lutheran Health System. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/26a92e1b-08d8-45cd-af0c-eaf2514808a2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.4 years (24,631 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 76 days; Disease response: Tumor Free.
- Days to follow up: 435 days (1.2 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 98; FEV1/FVC after bronchodilator (%): 82; FEV1/FVC before bronchodilator (%): 84; FEV1 after bronchodilator (% of reference): 85; FEV1 before bronchodilator (% of reference): 69.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1954; Tobacco smoking quit year: 1984.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L4-A4E6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-L4-A4E6-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide TCGA-L4-A4E6-01A-02-TSB: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-L4-A4E6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-L4-A4E6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 435 days; disease-specific survival: no event (censored), 435 days; disease-free interval: no event (censored), 435 days; progression-free interval: no event (censored), 435 days.
